Somatic mutation profile of tumor specimen TCGA-XF-AAMY-01A (aliquot TCGA-XF-AAMY-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 78.1 years (28,509 days).
Specimen TCGA-XF-AAMY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff251d6e-2c30-4e53-80c2-50dc7267ccf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMY-10A (Blood Derived Normal), aliquot TCGA-XF-AAMY-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75521f74-aa93-465c-9635-7e268ad1dd48

The open-access MAF lists 132 somatic variants for this specimen: 101 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 28, Nonsense Mutation 6, Frame Shift Del 3, RNA 3, Splice Region 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6B | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as rs1366870336, COSV50514887; called by muse, mutect2, varscan2
- ADAMTS9 | c.4181G>C p.C1394S | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55780686; called by muse, mutect2, varscan2
- ADGRL3 | c.886A>T p.I296L (on ENST00000506720 / NM_001322402.2; = p.I228L on NM_015236.6) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV72268269; called by muse, mutect2, varscan2
- ANPEP | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs373138765; called by muse, mutect2, varscan2
- ARFGEF1 | c.5072G>T p.R1691I | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV51608154; called by muse, mutect2
- ASH1L | c.5380C>T p.H1794Y | Missense Mutation (SNP) | VAF 95/155 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as COSV64207866; called by muse, mutect2, varscan2
- ATF1 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV50394524; called by muse, mutect2, varscan2
- ATP10D | c.2766C>A p.D922E | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56707235; called by muse, mutect2, varscan2
- ATP12A | c.1038T>A p.N346K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54515853; called by muse, mutect2, varscan2
- B4GALT3 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as COSV60527166; called by muse, mutect2
- BMS1 | c.778A>C p.R260= | Splice Region (SNP) | VAF 28/137 reads (20%) | catalogued as COSV65733826; called by muse, mutect2, varscan2
- BRAF | c.2203G>C p.E735Q (on ENST00000288602 / NM_001374244.1; = p.E695Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV56062510, COSV56125554, COSV56171407; called by muse, mutect2, varscan2
- C16orf70 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 32/275 reads (12%) | catalogued as COSV99531166; called by muse, mutect2, varscan2
- C3 | c.3361G>T p.D1121Y | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55572734; called by muse, mutect2, varscan2
- CD300C | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.192); catalogued as rs143534670, COSV58170450; called by muse, mutect2, varscan2
- CDO1 | c.375G>C p.L125F | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.658); catalogued as rs201131720, COSV51665182; called by muse, mutect2, varscan2
- CEP350 | c.7892G>C p.R2631T | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV62602153; called by muse, mutect2, varscan2
- CEP350 | c.8044G>C p.E2682Q | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.56); PolyPhen benign (0.139); catalogued as COSV62602166; called by muse, mutect2, varscan2
- COL11A2 | c.4055C>T p.P1352L (on ENST00000341947 / NM_080680.3; = p.P1245L on NM_080679.2) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs763995767, COSV59493121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.2704C>T p.L902F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); catalogued as COSV55088855; called by muse, mutect2, varscan2
- COL7A1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs942152368, COSV60395020; called by muse, mutect2, varscan2
- COQ3 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54639947; called by muse, varscan2
- CRIM1 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs377405765; called by muse, mutect2, varscan2
- CSPG4 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs750431851, COSV100413491; called by muse, mutect2, varscan2
- CUBN | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100912140; called by muse, mutect2, varscan2
- DCLK2 | c.894del p.S299Qfs*53 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as COSV56207176; called by mutect2, pindel, varscan2
- DDX51 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57958180; called by muse, mutect2, varscan2
- DYNC2H1 | c.5455C>G p.H1819D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV62093759; called by muse, mutect2, varscan2
- EEF1AKNMT | c.779G>T p.R260L (on ENST00000361735 / NM_015935.5; = p.R174L on NM_014955.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV62283018; called by muse, mutect2, varscan2
- FAM133B | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV101300196; called by muse, mutect2, varscan2
- GAB2 | c.1219G>C p.E407Q (on ENST00000361507 / NM_080491.3; = p.E369Q on NM_012296.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.638); catalogued as COSV60867797; called by muse, mutect2
- GIMAP5 | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV57529971; called by muse, mutect2, varscan2
- GJA1 | c.890_892del p.S297del | In Frame Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs976659652; called by pindel, varscan2
- GPN2 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV64652058; called by muse, mutect2, varscan2
- HECTD1 | c.5992G>C p.E1998Q | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV67946241; called by muse, mutect2, varscan2
- HNRNPUL1 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54562162; called by muse, mutect2, varscan2
- HSD17B11 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1156499891, COSV64154392, COSV64155014; called by muse, mutect2, varscan2
- IL12RB2 | c.663A>C p.I221= | Splice Region (SNP) | VAF 27/143 reads (19%) | catalogued as COSV52023354; called by muse, mutect2, varscan2
- IL20RA | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1281562622, COSV57358190; called by muse, mutect2, varscan2
- INSL6 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs971310807, COSV67562571, COSV67563158; called by muse, mutect2, varscan2
- IP6K2 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV60793610; called by muse, mutect2, varscan2
- IQCA1 | c.1318G>C p.V440L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54501619; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1458G>A p.M486I (on ENST00000485419 / NM_001197113.1; = p.M410I on NM_014575.3) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV61844783; called by muse, mutect2, varscan2
- ITGA11 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs369766881; called by muse, mutect2, varscan2
- KCNH4 | c.2425C>G p.Q809E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs1200545776, COSV52917294; called by muse, mutect2, varscan2
- KDM5B | c.4600C>T p.R1534C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs377525543; called by muse, mutect2, varscan2
- LAMA2 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70346686, COSV70352175; called by muse, mutect2, varscan2
- LAMB4 | c.5051G>A p.G1684E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV52718686; called by muse, mutect2, varscan2
- LINGO3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1479284977, COSV68261311; called by muse, mutect2, varscan2
- LTN1 | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1020357985, COSV63733763; called by muse, mutect2, varscan2
- LY75 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.138); catalogued as COSV55105389; called by muse, mutect2, varscan2
- MAP1LC3C | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV61803710; called by muse, mutect2, varscan2
- MDN1 | c.14879G>T p.G4960V | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV65521348; called by muse, mutect2, varscan2
- MED1 | c.3516G>A p.M1172I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV56124706; called by muse, mutect2, varscan2
- MTMR1 | c.1942T>C p.S648P | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV60936092; called by muse, mutect2, varscan2
- MYH13 | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52828203; called by muse, mutect2, varscan2
- NFX1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs772556996, COSV59310189; called by muse, mutect2, varscan2
- OR2T33 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs764655627, COSV100532385, COSV58815735, COSV58817782; called by muse, mutect2, varscan2
- OR52N2 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV57676786; called by muse, mutect2, varscan2
- PAN3 | c.1645G>A p.V549I | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs749723631, COSV56703156; called by muse, mutect2, varscan2
- PCSK1 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100226869; called by muse, mutect2
- PIK3CB | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV56685879, COSV56686015; called by muse, mutect2, varscan2
- PIP4P2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as rs745374056, COSV53438401; called by muse, mutect2, varscan2
- POM121C | c.910G>A p.E304K (on ENST00000607367; = p.E62K on NM_001099415.3) | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.821); catalogued as rs1554473868, COSV99992481; called by muse, mutect2, varscan2
- POU4F1 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV65884287; called by muse, mutect2, varscan2
- PTF1A | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.362); catalogued as COSV100919566; called by muse, mutect2
- RBM39 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99488289; called by muse, mutect2
- RELN | c.5077G>A p.D1693N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as rs1487716758, COSV59001001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOBTB1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1272297738, COSV61958517; called by muse, varscan2
- RNF139 | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV52679406; called by muse, mutect2, varscan2
- RNF139 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52679409; called by muse, mutect2, varscan2
- RPL5 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 36/121 reads (30%) | catalogued as COSV100240281; called by muse, mutect2, varscan2
- RPTN | c.1997T>C p.I666T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs529572350, COSV60167227; called by muse, mutect2, varscan2
- RYR1 | c.5954G>T p.S1985I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1441012614, COSV100614306, COSV62098536; called by muse, mutect2
- SALL2 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV58103268; called by muse, mutect2
- SAMD9L | c.3568G>A p.D1190N | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV59081439; called by muse, mutect2, varscan2
- SEC23A | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as rs1193530363, COSV100305094; called by muse, mutect2, varscan2
- SLC39A13 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs143199010; called by muse, mutect2, varscan2
- SLIT2 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs756812021, COSV56571632; called by muse, mutect2, varscan2
- SMARCB1 | c.946G>T p.E316* (on ENST00000263121; = p.E362* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 35/47 reads (74%) | catalogued as COSV99320157; called by muse, mutect2, varscan2
- SMARCC1 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV54380397; called by muse, mutect2, varscan2
- SPHKAP | c.844A>T p.K282* | Nonsense Mutation (SNP) | VAF 28/159 reads (18%) | catalogued as COSV100763755; called by muse, mutect2, varscan2
- SPTAN1 | c.2426C>G p.S809C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63987047; called by muse, mutect2, varscan2
- SRR | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60737153; called by muse, mutect2, varscan2
- ST3GAL2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 28/42 reads (67%) | PolyPhen possibly damaging (0.809); catalogued as COSV61596659, COSV61597314; called by muse, mutect2, varscan2
- STRC | c.4699C>G p.Q1567E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV55852399; called by muse, mutect2, varscan2
- STRC | c.4612C>G p.L1538V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV55852403, COSV55853142; called by muse, mutect2, varscan2
- STRC | c.4252C>G p.L1418V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100294447; called by muse, mutect2, varscan2
- TKTL1 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54212900; called by muse, mutect2, varscan2
- TMPRSS15 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53039508; called by muse, mutect2, varscan2
- TOGARAM2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1327703047, COSV101090913; called by muse, mutect2, varscan2
- TOMM20L | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV53621603; called by muse, mutect2, varscan2
- TRIB3 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs562068333, COSV53931291; called by muse, mutect2, varscan2
- USP8 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV56164169; called by muse, mutect2, varscan2
- VIRMA | c.179+1G>C p.X60_splice | Splice Site (SNP) | VAF 27/152 reads (18%) | catalogued as COSV52584862; called by muse, mutect2, varscan2
- ZNF283 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs373629233; called by muse, mutect2, varscan2
- DDX10 | c.1824_1827dup p.T610* | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel
- INO80 | c.1234del p.E412Kfs*4 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- IQCA1 | c.1311G>C p.R437S | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- PPIL4 | c.643_646delinsCTT p.K215Lfs*33 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by pindel, varscan2*
- TPTE | c.1602G>C p.E534D (on ENST00000618007 / NM_199261.4; = p.E516D on NM_199259.4) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2
- CCDC184 | c.315C>G p.V105= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100343919; called by muse, mutect2
- CETP | c.96C>A p.I32= | Silent (SNP) | VAF 48/77 reads (62%) | catalogued as COSV52362492; called by muse, mutect2, varscan2
- DPEP2 | c.1335C>T p.L445= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV52054556; called by muse, mutect2
- DTX3 | c.1017G>C p.L339= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as COSV54086500, COSV99677382; called by muse, mutect2, varscan2
- ETV7 | c.279C>T p.D93= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs755834466, COSV60316050; called by muse, mutect2, varscan2
- GLT6D1 | c.348C>T p.D116= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs754546707, COSV65627677; called by muse, mutect2, varscan2
- ICA1L | c.1137C>G p.L379= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV64173400; called by muse, mutect2, varscan2
- KDM1A | c.2082C>T p.F694= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV56501016; called by muse, mutect2, varscan2
- KIFC1 | c.1344G>C p.L448= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs778843801, COSV65737526; called by muse, mutect2, varscan2
- MAP3K15 | c.792G>A p.A264= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1229158453, COSV100135388, COSV58829814; called by muse, mutect2, varscan2
- MAPK8IP1 | c.2016C>T p.H672= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs749578837, COSV53797760; called by muse, mutect2, varscan2
- MEMO1 | c.255C>G p.L85= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV54451972; called by muse, mutect2, varscan2
- MMP1 | c.1401G>A p.R467= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100187801; called by muse, mutect2
- MUC4 | c.15415C>T p.L5139= (on ENST00000463781 / NM_018406.7; = p.L903= on NM_004532.6) | Silent (SNP) | VAF 98/144 reads (68%) | catalogued as COSV57779557; called by muse, mutect2, varscan2
- MXRA5 | c.4713T>C p.S1571= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV54234459; called by muse, mutect2, varscan2
- NOG | c.57G>A p.G19= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100240521; called by muse, mutect2
- NUP210 | c.1575C>T p.F525= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs202170701, COSV54406187; called by muse, mutect2, varscan2
- PLXNC1 | c.2577G>A p.L859= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV51575021; called by muse, mutect2, varscan2
- SDK1 | c.5574G>A p.G1858= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV67368008; called by muse, mutect2, varscan2
- SPTA1 | c.2451T>A p.T817= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV63752781; called by muse, mutect2, varscan2
- SPTAN1 | c.2307C>G p.L769= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV63987042; called by muse, mutect2, varscan2
- TNR | c.2100C>G p.T700= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV54884700, COSV54887219; called by muse, mutect2, varscan2
- VPS13B | c.8961C>T p.P2987= | Silent (SNP) | VAF 73/312 reads (23%) | catalogued as COSV62141200; called by muse, mutect2, varscan2
- ZFHX3 | c.1071C>T p.L357= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs1184474197, COSV51717959, COSV51730352; called by muse, mutect2, varscan2
- ZFHX4 | c.8625C>T p.F2875= | Silent (SNP) | VAF 68/78 reads (87%) | catalogued as COSV50772527; called by muse, mutect2, varscan2
- ZNF106 | c.3315G>A p.L1105= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV55516560; called by muse, mutect2, varscan2
- ZNF248 | c.987G>A p.V329= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV61997671; called by muse, mutect2, varscan2
- ZNF615 | c.996T>G p.T332= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV65033158; called by muse, mutect2, varscan2
- AC024940.1 | n.3304C>T | RNA (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- SNORD115-22 | n.12G>A | RNA (SNP) | VAF 66/448 reads (15%) | called by muse, mutect2, varscan2
- STAG3L4 | n.636C>T | RNA (SNP) | VAF 49/142 reads (35%) | catalogued as rs371406310; called by muse, mutect2, varscan2
